Somatic mutation profile of tumor specimen C3L-07213-01 (aliquot CPT0407970010) from CPTAC case C3L-07213, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 28.1 years (10,254 days).
Specimen C3L-07213-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3db5735-8997-4c1a-9d5b-dffb8fcdfc63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07213-31 (Blood Derived Normal), aliquot CPT0408780002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a48ac5bc-be81-4ef6-9e81-938c8d8e6341

The open-access MAF lists 42 somatic variants for this specimen: 30 protein-altering or splice-affecting, 6 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 6, Intron 3, 5'Flank 2, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF1AX | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 18/48 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.693); catalogued as COSV63309291, COSV63309392, COSV63309466; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 60/205 reads (29%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 28/73 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 186/574 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP13A2 | c.1384C>T p.L462F | Missense Mutation (SNP) | VAF 30/280 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs773341880; called by muse, mutect2, varscan2
- CCDC86 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771726549; called by muse, mutect2, varscan2
- CRYBB3 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 36/573 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs990563364, COSV53194642; called by muse, mutect2
- DHX34 | c.497A>G p.Q166R | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.081); catalogued as rs368831190; called by muse, mutect2, varscan2
- IL21R | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 158/451 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.127); catalogued as rs780430063, COSV61970468; called by muse, mutect2, varscan2
- LRRN1 | c.1301G>C p.R434P | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.204); catalogued as COSV60014930; called by muse, mutect2, varscan2
- POLR1B | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.953); catalogued as rs781571201; called by muse, mutect2, varscan2
- RGS1 | c.541C>A p.L181I | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1326882765; called by muse, mutect2, varscan2
- TP53 | c.318C>G p.S106R | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.149); catalogued as rs1555526581, CM013441, COSV52748282, COSV52919256, COSV53146850; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR81 | c.541C>G p.L181V | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1451637048; called by muse, mutect2, varscan2
- WNK4 | c.3592C>T p.R1198C | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745774737; called by muse, mutect2, varscan2
- ZSWIM9 | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 99/243 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1211190664; called by muse, mutect2, varscan2
- CADM2 | c.1138G>C p.V380L (on ENST00000407528 / NM_001167674.2; = p.V382L on NM_153184.4) | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- CCAR2 | c.1721_1724del p.E574Gfs*41 | Frame Shift Del (DEL) | VAF 111/400 reads (28%) | called by mutect2, pindel, varscan2
- HIVEP3 | c.6327C>G p.D2109E | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- LEMD3 | c.1805T>G p.L602W | Missense Mutation (SNP) | VAF 37/194 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MYORG | c.1018A>T p.I340F | Missense Mutation (SNP) | VAF 118/235 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUP188 | c.1936G>A p.V646I | Missense Mutation (SNP) | VAF 43/267 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PLOD2 | c.1826A>G p.D609G | Missense Mutation (SNP) | VAF 91/204 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- POM121C | c.3161G>C p.G1054A (on ENST00000607367; = p.G812A on NM_001099415.3) | Missense Mutation (SNP) | VAF 53/215 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAG2 | c.1060G>C p.D354H | Missense Mutation (SNP) | VAF 88/285 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- SLC6A14 | c.1089T>A p.F363L | Missense Mutation (SNP) | VAF 52/266 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- TCHHL1 | c.940T>A p.S314T | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- TENM3 | c.4621T>G p.Y1541D | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- TERT | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 22/414 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.183); called by muse, mutect2
- TMEM131 | c.2823G>C p.K941N | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- AATK | c.264C>T p.N88= | Silent (SNP) | VAF 91/282 reads (32%) | catalogued as rs769377644; called by muse, mutect2, varscan2
- ABTB1 | c.957C>T p.A319= (on ENST00000232744 / NM_172027.3; = p.A177= on NM_032548.3) | Silent (SNP) | VAF 79/239 reads (33%) | catalogued as rs775415899, COSV51742940; called by muse, mutect2, varscan2
- CAPN13 | c.1461T>C p.H487= | Silent (SNP) | VAF 61/236 reads (26%) | called by muse, mutect2, varscan2
- IGHA2 | c.399G>A p.T133= | Silent (SNP) | VAF 164/516 reads (32%) | catalogued as rs771521034; called by muse, mutect2, varscan2
- NPHS1 | c.3453G>A p.P1151= | Silent (SNP) | VAF 213/628 reads (34%) | catalogued as rs905105064, COSV62289963; called by muse, mutect2, varscan2
- PLXNC1 | c.1572G>T p.V524= | Silent (SNP) | VAF 41/107 reads (38%) | called by muse, mutect2, varscan2
- CTDSP1 | chr2:218398476 C>T | 5'Flank (SNP) | VAF 23/100 reads (23%) | called by muse, mutect2, varscan2
- GOLGA8J | c.591+281G>A | Intron (SNP) | VAF 42/160 reads (26%) | called by mutect2, varscan2
- NKX3-2 | chr4:13547112 G>T | 5'Flank (SNP) | VAF 44/111 reads (40%) | called by muse, mutect2, varscan2
- PPP5C | c.634-97T>G | Intron (SNP) | VAF 16/518 reads (3%) | called by muse, mutect2
- SNORD116-12 | n.50T>C | RNA (SNP) | VAF 47/144 reads (33%) | called by muse, mutect2, varscan2
- SNX32 | c.785+11_785+20del | Intron (DEL) | VAF 43/128 reads (34%) | called by mutect2, pindel, varscan2
